Somatic mutation profile of tumor specimen BLGSP-71-06-00170-01A (aliquot BLGSP-71-06-00170-01A-01D-A663-33) from CGCI case BLGSP-71-06-00170, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a1cd658-2df8-4694-9ac9-83c27b25742d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00170-99A (Granulocytes), aliquot BLGSP-71-06-00170-99A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25b4bf94-69b7-4126-987d-369a7e9372cc

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPU | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs1057524915, CM1410654, COSV51690756, COSV51691348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 44/95 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ID3 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1055074154, COSV65800845, COSV65801501; called by muse, varscan2
- PCBP1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | catalogued as rs797044899, COSV57851598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.3704A>G p.D1235G | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV60789187; called by muse, mutect2, varscan2
- CIITA | c.1340T>C p.F447S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- P2RY8 | c.523T>C p.C175R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYC | c.-329G>C | 5'UTR (SNP) | VAF 12/25 reads (48%) | catalogued as COSV104388183, COSV52378269; called by muse, mutect2, varscan2
- MYC | c.-172C>G | 5'UTR (SNP) | VAF 44/96 reads (46%) | catalogued as COSV52374541, COSV99420854; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975294 A>T | 5'Flank (SNP) | VAF 84/100 reads (84%) | catalogued as rs746694203; called by muse, varscan2
